Somatic mutation profile of tumor specimen TARGET-10-PASXLZ-09A (aliquot TARGET-10-PASXLZ-09A-01D) from TARGET case TARGET-10-PASXLZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.2 years (1,910 days).
Specimen TARGET-10-PASXLZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c2e513d-5996-40f4-9437-42b79b8b69b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASXLZ-10A (Blood Derived Normal), aliquot TARGET-10-PASXLZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7141a1b7-300f-41b3-b2fe-f8f7f1cc7fb8

The open-access MAF lists 22 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, Intron 3, Frame Shift Ins 2, Nonsense Mutation 2, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DAAM1 | c.983T>G p.L328* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as COSV62833933; called by mutect2, varscan2
- FBN2 | c.926A>C p.Q309P | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.798); catalogued as COSV52491148; called by muse, mutect2, varscan2
- GREB1 | c.611G>C p.G204A | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV52179873; called by muse, mutect2, varscan2
- NOTCH1 | c.4778T>C p.L1593P | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53024711; called by muse, mutect2, varscan2
- OR5B3 | c.582G>T p.E194D | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.424); catalogued as COSV58678759; called by muse, mutect2
- SLITRK3 | c.2044C>T p.R682C | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV53845401, COSV53849374; called by muse, mutect2, varscan2
- TIAM2 | c.3887delinsAG p.I1296Kfs*3 | Frame Shift Ins (INS) | VAF 22/75 reads (29%) | catalogued as COSV51637443; called by mutect2*, pindel, varscan2*
- TRAPPC8 | c.1709G>A p.R570Q | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1435924998, COSV51966807; called by muse, mutect2, varscan2
- ATP5MC3 | c.330G>T p.K110N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.392); called by mutect2, varscan2
- MROH2A | c.1516G>A p.D506N | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- SOAT2 | c.95_96insTTTCTAATC p.T32_H33insF* | Nonsense Mutation (INS) | VAF 57/143 reads (40%) | called by mutect2, pindel, varscan2
- TIAM2 | c.3886dup p.I1296Nfs*3 | Frame Shift Ins (INS) | VAF 16/45 reads (36%) | called by mutect2, varscan2
- WNK4 | c.3323C>A p.P1108Q | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2
- CYFIP1 | c.3675C>T p.Y1225= | Silent (SNP) | VAF 34/50 reads (68%) | called by muse, mutect2, varscan2
- MYO1F | c.2478G>T p.T826= | Silent (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2
- PUS1 | c.993C>T p.L331= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs139335343, COSV100435140; called by muse, varscan2
- TMPRSS7 | c.2298C>T p.Y766= (on ENST00000452346; = p.Y640= on NM_001042575.2) | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as rs377496128; called by muse, mutect2, varscan2
- ACTR1A | c.*1191G>T | 3'UTR (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2
- AK9 | c.3633+13del | Intron (DEL) | VAF 10/57 reads (18%) | catalogued as rs577355457, COSV58140597, COSV58141900; called by pindel, varscan2
- BCL11A | c.386-6359G>T | Intron (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- HSD17B7P2 | n.705C>A | RNA (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2
- MLIP | c.613-11326C>A | Intron (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2, varscan2
